Somatic mutation profile of tumor specimen TCGA-AA-3977-01A (aliquot TCGA-AA-3977-01A-01D-1981-10) from TCGA case TCGA-AA-3977, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; Age at diagnosis: 65.2 years (23,832 days).
Specimen TCGA-AA-3977-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee8c2ea1-6334-4c40-93b0-25eb4787ac49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3977-10A (Blood Derived Normal), aliquot TCGA-AA-3977-10A-01W-0999-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ac69fd7-b6a6-4aa7-8d8d-f7bce759f0e6

The open-access MAF lists 4,659 somatic variants for this specimen: 3,700 protein-altering or splice-affecting, 862 silent, 97 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,177, Silent 862, Nonsense Mutation 437, Splice Site 43, Intron 41, RNA 33, Splice Region 22, 3'UTR 10, Frame Shift Ins 9, Frame Shift Del 6, 3'Flank 5, 5'Flank 5.

Variants (750 of 4,659; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 60/183 reads (33%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CACNA1F | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 29/57 reads (51%) | catalogued as rs797044676, CM010174, COSV59903636; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLN5 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 22/107 reads (21%) | catalogued as rs386833971, CM120887, COSV66285061; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CSPP1 | c.1255C>T p.R419* (on ENST00000676605; = p.R378* on NM_024790.6) | Nonsense Mutation (SNP) | VAF 66/174 reads (38%) | catalogued as rs374703898, CM140106, COSV51580938; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GNAQ | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 10/186 reads (5%) | hotspot (GDC flag); catalogued as COSV54106777, COSV99680195; called by muse, mutect2
- KCNQ1 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.642); catalogued as rs149089817; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.351A>C p.K117N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MECOM | c.2542C>T p.R848* (on ENST00000468789 / NM_001105078.4; = p.R1036* on NM_004991.4) | Nonsense Mutation (SNP) | VAF 11/158 reads (7%) | catalogued as rs1560118923, COSV52968817; ClinVar: pathogenic; called by muse, mutect2
- MED12 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 77/110 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199469669, COSV61329437, COSV61329567, COSV61330093; ClinVar: not provided; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 51/154 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3129G>T p.M1043I | Missense Mutation (SNP) | VAF 42/123 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 36/309 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 153/450 reads (34%) | catalogued as rs1114167674, CM110151, COSV64293312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.207G>T p.E69D | Missense Mutation (SNP) | VAF 33/163 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen benign (0.11); catalogued as COSV100692084, COSV61005894; called by muse, mutect2, varscan2
- SCN1A | c.2584C>T p.R862* (on ENST00000303395 / NM_001202435.3; = p.R851* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 44/115 reads (38%) | catalogued as rs397514459, CM093370, CM116003, COSV57665384; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SGCB | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 14/266 reads (5%) | catalogued as rs1013015106, COSV67340757; ClinVar: pathogenic; called by muse, mutect2
- SMCHD1 | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs886042392; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- TP53 | c.395A>C p.K132T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519996, COSV52666637, COSV52701687, COSV52759171; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1760G>A p.R587Q (on ENST00000373993 / NM_138932.2; = p.R579Q on NM_014576.4) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.968); catalogued as rs530902814, COSV50965034; called by muse, mutect2, varscan2
- A1CF | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 32/102 reads (31%) | catalogued as rs772118222, COSV50957228; called by muse, varscan2
- AACS | c.192G>T p.E64D | Missense Mutation (SNP) | VAF 59/389 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.046); catalogued as COSV99907705; called by muse, mutect2, varscan2
- AARS1 | c.2782G>A p.D928N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV99933165; called by muse, mutect2, varscan2
- AASDH | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1217671487, COSV52711119; called by muse, mutect2, varscan2
- AASS | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100741642, COSV100741808; called by muse, mutect2, varscan2
- ABCA1 | c.371A>G p.D124G | Missense Mutation (SNP) | VAF 76/247 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV101035491; called by muse, mutect2, varscan2
- ABCA12 | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); catalogued as rs1283642196, COSV55954325, COSV99788064, COSV99791861; called by muse, mutect2, varscan2
- ABCA13 | c.1734G>A p.W578* | Nonsense Mutation (SNP) | VAF 21/141 reads (15%) | catalogued as COSV101329904; called by muse, mutect2, varscan2
- ABCA13 | c.4769T>C p.V1590A | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV70031327; called by muse, mutect2, varscan2
- ABCA13 | c.6427G>T p.E2143* | Nonsense Mutation (SNP) | VAF 27/77 reads (35%) | catalogued as COSV101329905; called by muse, mutect2, varscan2
- ABCA13 | c.8525G>T p.R2842I | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV71286080, COSV71288716; called by muse, mutect2
- ABCA13 | c.10903G>A p.V3635I | Missense Mutation (SNP) | VAF 76/422 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs570952854, COSV101446729; called by muse, mutect2, varscan2
- ABCA13 | c.11291G>T p.S3764I | Missense Mutation (SNP) | VAF 54/914 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV101446730; called by muse, mutect2
- ABCA13 | c.14476C>T p.R4826C | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs200851445; called by muse, mutect2, varscan2
- ABCA3 | c.1213C>A p.L405I | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.196); catalogued as COSV100067953; called by muse, mutect2, varscan2
- ABCA4 | c.4641G>T p.K1547N | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV100933014; called by muse, mutect2
- ABCA4 | c.1923C>A p.C641* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100933016; called by muse, mutect2, varscan2
- ABCA5 | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as rs753649836, COSV101200961; called by muse, mutect2, varscan2
- ABCA5 | c.1723G>T p.E575* | Nonsense Mutation (SNP) | VAF 33/83 reads (40%) | catalogued as COSV101200963; called by muse, mutect2, varscan2
- ABCA5 | c.1507G>T p.D503Y | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101200965; called by muse, mutect2
- ABCA6 | c.1307A>C p.N436T | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV99445694; called by muse, mutect2, varscan2
- ABCA8 | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0.026); catalogued as rs768333090, COSV52197981; called by muse, mutect2, varscan2
- ABCA9 | c.4735G>A p.D1579N | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs1455091157, COSV100382553; called by muse, mutect2, varscan2
- ABCA9 | c.4482G>T p.M1494I | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.362); catalogued as COSV100382554; called by muse, mutect2, varscan2
- ABCA9 | c.3687G>T p.K1229N | Missense Mutation (SNP) | VAF 105/279 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV100382555; called by muse, mutect2, varscan2
- ABCA9 | c.3260T>A p.I1087K | Missense Mutation (SNP) | VAF 69/214 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.689); catalogued as COSV100382557; called by muse, varscan2
- ABCA9 | c.1649G>T p.R550I | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100382558; called by muse, mutect2
- ABCB1 | c.36G>T p.K12N | Missense Mutation (SNP) | VAF 108/311 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV99712004; called by muse, mutect2, varscan2
- ABCB11 | c.3113C>T p.T1038I | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99791466; called by muse, mutect2, varscan2
- ABCB11 | c.1738C>A p.L580M | Missense Mutation (SNP) | VAF 102/336 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99791472; called by muse, mutect2, varscan2
- ABCB5 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 52/278 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs368226947; called by muse, mutect2, varscan2
- ABCB7 | c.956G>T p.R319I (on ENST00000373394 / NM_001271696.3; = p.R320I on NM_004299.6) | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99504591; called by muse, mutect2
- ABCC5 | c.2473C>T p.P825S | Missense Mutation (SNP) | VAF 168/605 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99656322; called by muse, mutect2, varscan2
- ABCC8 | c.3749G>A p.R1250Q | Missense Mutation (SNP) | VAF 107/306 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs975856232, COSV56860358; called by muse, varscan2
- ABCC8 | c.3682G>A p.E1228K | Missense Mutation (SNP) | VAF 136/397 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs758995284, COSV56858022; called by muse, varscan2
- ABCC8 | c.2553C>A p.F851L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100216531, COSV56848229; called by muse, mutect2, varscan2
- ABCD2 | c.991A>T p.N331Y | Missense Mutation (SNP) | VAF 51/327 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV100429115; called by muse, mutect2, varscan2
- ABCD2 | c.701A>G p.D234G | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100429118, COSV58050699; called by muse, mutect2, varscan2
- ABCG2 | c.21A>C p.E7D | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs747453638, COSV99418377; called by muse, mutect2, varscan2
- ABHD3 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 45/126 reads (36%) | catalogued as COSV100004176; called by muse, mutect2, varscan2
- ABHD3 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 45/125 reads (36%) | catalogued as COSV100004179; called by muse, mutect2, varscan2
- ABI1 | c.1265A>C p.E422A | Missense Mutation (SNP) | VAF 139/359 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV100697697; called by muse, mutect2, varscan2
- ABI3BP | c.1996C>T p.H666Y | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99425178; called by muse, mutect2, varscan2
- ABTB2 | c.2484G>T p.K828N | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.079); catalogued as rs749055024, COSV100130572; called by muse, mutect2, varscan2
- AC090517.4 | c.1885A>G p.T629A | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.028); catalogued as rs995380074, COSV99974019; called by muse, mutect2, varscan2
- AC245748.1 | c.16-1G>T p.X6_splice | Splice Site (SNP) | VAF 30/105 reads (29%) | catalogued as COSV100495441; called by muse, mutect2, varscan2
- ACACB | c.2476C>A p.L826I | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as COSV100622246; called by muse, mutect2, varscan2
- ACADSB | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 148/441 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.584); catalogued as rs745481903, COSV62551017; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACADSB | c.567G>T p.K189N | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100715061; called by muse, mutect2, varscan2
- ACBD5 | c.1051C>T p.R351C (on ENST00000375888 / NM_001352568.1; = p.R342C on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs755306488, COSV65517960; called by muse, mutect2, varscan2
- ACE2 | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 80/118 reads (68%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as rs865959788, COSV99382506; called by muse, mutect2, varscan2
- ACER1 | c.101A>G p.N34S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.621); catalogued as COSV100033918; called by muse, mutect2, varscan2
- ACIN1 | c.3841C>T p.R1281W | Missense Mutation (SNP) | VAF 102/264 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV99398963; called by muse, varscan2
- ACO2 | c.447A>C p.E149D | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); catalogued as COSV99346954; called by muse, mutect2, varscan2
- ACOT11 | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 28/108 reads (26%) | catalogued as rs377475734; called by muse, mutect2, varscan2
- ACOT12 | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 52/137 reads (38%) | catalogued as COSV100296695; called by muse, mutect2, varscan2
- ACOX3 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs756175928, COSV62711951; called by muse, mutect2, varscan2
- ACP3 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.066); catalogued as rs777654881, COSV60484679; called by muse, mutect2, varscan2
- ACP5 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as rs922892618, COSV99520165, COSV99520252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACSL3 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 97/309 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1177812495, COSV62483596, COSV62485156; called by muse, mutect2, varscan2
- ACSL4 | c.1960C>T p.R654* (on ENST00000340800 / NM_022977.2; = p.R613* on NM_004458.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as CM151038, COSV100538347, COSV61614626; called by muse, mutect2, varscan2
- ACSL5 | c.1078G>T p.D360Y (on ENST00000354273; = p.D416Y on NM_016234.3) | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100634450, COSV100634463; called by muse, mutect2, varscan2
- ACTBL2 | c.1026T>G p.I342M | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.753); catalogued as COSV101379218; called by muse, varscan2
- ACTRT1 | c.1118G>T p.R373I | Missense Mutation (SNP) | VAF 56/87 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64418954, COSV64420046; called by muse, mutect2, varscan2
- ADAM12 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs374529217, COSV64105363; called by mutect2, varscan2
- ADAM17 | c.1891A>G p.T631A | Missense Mutation (SNP) | VAF 55/237 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV100176001; called by muse, mutect2, varscan2
- ADAM21 | c.1190C>A p.P397H | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as COSV99960428; called by muse, mutect2, varscan2
- ADAM21 | c.1790T>C p.L597S | Missense Mutation (SNP) | VAF 109/337 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV99960433; called by muse, mutect2, varscan2
- ADAM29 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV63669214; called by muse, mutect2, varscan2
- ADAM30 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 77/262 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs781229975, COSV65560969; called by muse, mutect2, varscan2
- ADAM8 | c.2048G>A p.S683N | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV101291594; called by muse, mutect2, varscan2
- ADAMDEC1 | c.407C>A p.S136Y | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753833406, COSV56474653, COSV99835826; called by muse, varscan2
- ADAMTS14 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV100941321; called by muse, mutect2, varscan2
- ADAMTS14 | c.3392C>T p.A1131V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1212996063, COSV64604450; called by muse, mutect2, varscan2
- ADAMTS16 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754295364, COSV57009975; called by muse, mutect2, varscan2
- ADAMTS16 | c.2761C>T p.P921S | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV57007015; called by muse, mutect2, varscan2
- ADAMTS18 | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.322); catalogued as rs779170683, COSV51399738; called by mutect2, varscan2
- ADAMTS18 | c.1106G>A p.C369Y | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99271012; called by muse, mutect2, varscan2
- ADAMTS18 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs891093965, COSV51399337; called by mutect2, varscan2
- ADAMTS2 | c.965G>A p.S322N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as rs201702236; called by muse, mutect2
- ADAMTS3 | c.1666T>C p.S556P | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.12); catalogued as rs958050802, COSV99710072; called by muse, mutect2, varscan2
- ADAMTS3 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV99710074; called by muse, mutect2, varscan2
- ADAMTS9 | c.4166G>A p.G1389D | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs757408086, COSV99898613; called by muse, mutect2, varscan2
- ADAMTSL1 | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.621); catalogued as COSV52816905, COSV99440721; called by muse, varscan2
- ADAMTSL1 | c.2165C>T p.A722V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV101001203; called by muse, mutect2, varscan2
- ADAMTSL2 | c.825G>T p.K275N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV100618940; called by muse, mutect2
- ADAMTSL3 | c.1002C>A p.F334L | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.294); catalogued as COSV54472187, COSV99716713; called by muse, mutect2, varscan2
- ADAR | c.3657G>T p.K1219N | Missense Mutation (SNP) | VAF 104/300 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52713651; called by muse, mutect2, varscan2
- ADAT2 | c.572C>A p.S191Y | Missense Mutation (SNP) | VAF 64/280 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV99395582; called by muse, mutect2, varscan2
- ADCY2 | c.1006A>T p.I336F | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100601640; called by muse, mutect2
- ADCY2 | c.2362T>C p.Y788H | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV100601641; called by muse, mutect2, varscan2
- ADCY8 | c.3487G>T p.G1163* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV53901919, COSV99650540; called by muse, mutect2, varscan2
- ADCY9 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs772697228, COSV53574136; called by muse, mutect2, varscan2
- ADCYAP1 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.175); catalogued as rs1487295797, COSV52487224; called by muse, mutect2, varscan2
- ADGRB3 | c.1846C>A p.L616I | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100999632; called by muse, varscan2
- ADGRD1 | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs761685448, COSV55460845; called by muse, mutect2, varscan2
- ADGRE1 | c.68G>T p.R23I | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99165008; called by muse, mutect2, varscan2
- ADGRE1 | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 52/124 reads (42%) | catalogued as COSV51671532, COSV51672387; called by muse, mutect2, varscan2
- ADGRG4 | c.3917A>C p.K1306T | Missense Mutation (SNP) | VAF 99/147 reads (67%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99794219; called by muse, mutect2, varscan2
- ADGRG4 | c.7887C>A p.F2629L | Missense Mutation (SNP) | VAF 101/169 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1334865153, COSV99794222; called by muse, mutect2, varscan2
- ADGRG4 | c.9090G>T p.K3030N | Missense Mutation (SNP) | VAF 125/171 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as COSV54963432, COSV99794228; called by muse, mutect2, varscan2
- ADGRL2 | c.3118G>A p.A1040T (on ENST00000370717 / NM_001366005.1; = p.A1027T on NM_012302.4) | Missense Mutation (SNP) | VAF 66/276 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1470284505, COSV54663803, COSV54665192; called by muse, mutect2, varscan2
- ADGRL3 | c.1717G>T p.E573* (on ENST00000506720 / NM_001322402.2; = p.E505* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV72232225; called by muse, mutect2, varscan2
- ADGRL3 | c.3752G>A p.R1251Q (on ENST00000506720 / NM_001322402.2; = p.R1183Q on NM_015236.6) | Missense Mutation (SNP) | VAF 88/259 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1189094336, COSV72229226; called by muse, varscan2
- ADGRL3 | c.3974G>T p.S1325I (on ENST00000506720 / NM_001322402.2; = p.S1214I on NM_015236.6) | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV72232226; called by muse, mutect2, varscan2
- ADGRV1 | c.8124G>T p.Q2708H | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV101315411; called by muse, mutect2, varscan2
- ADGRV1 | c.9071A>G p.Y3024C | Missense Mutation (SNP) | VAF 107/452 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.526); catalogued as COSV67979166; called by muse, mutect2, varscan2
- ADIPOQ | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs777244635, COSV100292068; called by muse, mutect2, varscan2
- ADORA2A | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100418115; called by muse, mutect2, varscan2
- ADRA1B | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as rs1330843392, COSV100140049; called by muse, mutect2, varscan2
- AFF1 | c.1025C>A p.S342Y | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV57125539; called by muse, mutect2, varscan2
- AFF3 | c.371C>A p.S124Y | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.361); catalogued as COSV100417480, COSV57840534; called by muse, mutect2, varscan2
- AFP | c.148T>G p.F50V | Missense Mutation (SNP) | VAF 91/388 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99889638; called by muse, mutect2, varscan2
- AFP | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.272); catalogued as COSV99889641; called by muse, mutect2, varscan2
- AFTPH | c.1506G>T p.Q502H | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV99480261; called by muse, mutect2, varscan2
- AGAP1 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs777883161, COSV58327760; called by muse, mutect2, varscan2
- AGAP2 | c.1655G>A p.G552E (on ENST00000547588 / NM_001122772.2; = p.G216E on NM_014770.4) | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99222135; called by muse, mutect2, varscan2
- AGBL1 | c.1100A>C p.K367T | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV101222162; called by muse, mutect2, varscan2
- AGL | c.3757C>T p.R1253C | Missense Mutation (SNP) | VAF 87/466 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs375531470; called by muse, mutect2, varscan2
- AGPAT5 | c.204T>G p.N68K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV53449597; called by muse, mutect2
- AHCTF1 | c.2900A>G p.D967G (on ENST00000366508; = p.D941G on NM_015446.5) | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.359); catalogued as COSV100403043; called by muse, varscan2
- AHCTF1 | c.1229C>T p.S410L (on ENST00000366508; = p.S384L on NM_015446.5) | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58246164; called by muse, mutect2, varscan2
- AHCTF1 | c.730C>T p.R244C (on ENST00000366508; = p.R218C on NM_015446.5) | Missense Mutation (SNP) | VAF 92/336 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753602111, COSV58254928; called by muse, mutect2, varscan2
- AHCYL2 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV100272823; called by muse, mutect2, varscan2
- AHSG | c.685T>G p.F229V | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99889811; called by muse, mutect2
- AK8 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.369); catalogued as rs750120409, COSV53754113; called by muse, varscan2
- AKAP12 | c.3844G>A p.E1282K | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs368517285; called by muse, mutect2, varscan2
- AKAP3 | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 22/46 reads (48%) | catalogued as COSV99961729; called by muse, mutect2, varscan2
- AKAP6 | c.2354T>C p.V785A | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99797939; called by muse, varscan2
- AKAP6 | c.3330G>T p.K1110N | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV99797944; called by muse, mutect2, varscan2
- AKAP6 | c.6104A>G p.N2035S | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99797948; called by muse, mutect2, varscan2
- AKAP8L | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.704); catalogued as rs1287773316, COSV101275793; called by muse, mutect2, varscan2
- AKAP9 | c.11206C>T p.R3736* (on ENST00000359028; = p.R3712* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/103 reads (12%) | catalogued as rs1234676587, COSV62354774; called by muse, mutect2, varscan2
- AL592490.1 | c.2179A>C p.K727Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.892); catalogued as COSV69428336; called by muse, mutect2, varscan2
- ALAS1 | c.504G>T p.K168N | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV100050187; called by muse, mutect2, varscan2
- ALDH1A1 | c.1436G>T p.G479V | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99920986; called by muse, mutect2, varscan2
- ALDH1A3 | c.376T>A p.F126I | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100320220; called by muse, mutect2, varscan2
- ALDH1L1 | c.1041C>A p.F347L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1048277457, COSV99856448; called by muse, mutect2, varscan2
- ALDH8A1 | c.1413G>T p.K471N | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV99664387; called by muse, mutect2, varscan2
- ALG10 | c.159C>A p.F53L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99847882; called by muse, mutect2, varscan2
- ALK | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.159); catalogued as rs1267142388, COSV101201064; called by muse, mutect2, varscan2
- ALKBH2 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 22/139 reads (16%) | catalogued as COSV99655166; called by muse, mutect2, varscan2
- ALMS1 | c.1579G>T p.E527* | Nonsense Mutation (SNP) | VAF 105/281 reads (37%) | catalogued as rs759021934, COSV100040985; called by muse, mutect2, varscan2
- ALMS1 | c.6269C>A p.S2090Y | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV100040987; called by muse, varscan2
- ALOX15B | c.711C>A p.F237L | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV101205561; called by muse, mutect2
- ALOX5 | c.599C>A p.S200Y | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100979934; called by muse, mutect2, varscan2
- ALPK1 | c.2870C>A p.S957Y | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51584459, COSV99452703; called by muse, mutect2, varscan2
- ALPK2 | c.5250G>T p.K1750N | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as COSV64491095; called by muse, varscan2
- ALPK2 | c.2561C>A p.S854Y | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.862); catalogued as COSV64491420; called by muse, mutect2, varscan2
- ALPP | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 88/357 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs750197275; called by muse, mutect2, varscan2
- AMER1 | c.2570G>A p.R857Q | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs758807218, COSV100365211; called by muse, mutect2, varscan2
- AMMECR1 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 49/61 reads (80%) | catalogued as COSV99466195; called by muse, mutect2, varscan2
- AMPD3 | c.716A>G p.E239G (on ENST00000396553 / NM_001025389.2; = p.E248G on NM_000480.3) | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV101158072; called by muse, mutect2, varscan2
- AMZ2 | c.684C>A p.D228E | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.046); catalogued as COSV100703080; called by muse, mutect2, varscan2
- ANAPC1 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV100595194, COSV61974777; called by muse, mutect2, varscan2
- ANAPC1 | c.1286A>C p.K429T | Missense Mutation (SNP) | VAF 182/736 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV100594489; called by muse, varscan2
- ANGPTL1 | c.141G>T p.K47N | Missense Mutation (SNP) | VAF 219/667 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.15); catalogued as COSV52366100; called by muse, mutect2, varscan2
- ANGPTL3 | c.644C>A p.S215Y | Missense Mutation (SNP) | VAF 35/498 reads (7%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.556); catalogued as COSV51995482; called by muse, mutect2
- ANGPTL5 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs758888750, COSV100527609; called by muse, mutect2, varscan2
- ANK1 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs769707255, COSV99223750; called by muse, mutect2, varscan2
- ANK2 | c.9985T>G p.F3329V | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV99999330; called by muse, mutect2, varscan2
- ANK3 | c.6902C>A p.S2301Y | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); catalogued as COSV99778088; called by muse, mutect2, varscan2
- ANK3 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55065523; called by muse, mutect2, varscan2
- ANKH | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99414404; called by muse, mutect2, varscan2
- ANKMY2 | c.1248G>T p.K416N | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV100186835; called by muse, mutect2, varscan2
- ANKRD1 | c.796A>G p.K266E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as rs759544911, COSV100865277; called by mutect2, varscan2
- ANKRD13A | c.148T>C p.S50P | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99923819; called by muse, mutect2, varscan2
- ANKRD17 | c.3193G>A p.A1065T | Missense Mutation (SNP) | VAF 102/239 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV100428468; called by muse, mutect2, varscan2
- ANKRD26 | c.4703C>A p.S1568Y | Missense Mutation (SNP) | VAF 123/356 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV101062889; called by muse, mutect2, varscan2
- ANKRD26 | c.3512T>G p.F1171C | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV101062891; called by muse, mutect2, varscan2
- ANKRD30A | c.715G>T p.V239L (on ENST00000611781; = p.V183L on NM_052997.2) | Missense Mutation (SNP) | VAF 98/272 reads (36%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV100652817; called by muse, varscan2
- ANKRD30A | c.3565G>A p.E1189K (on ENST00000611781; = p.E1133K on NM_052997.2) | Missense Mutation (SNP) | VAF 41/230 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV100654309; called by muse, mutect2, varscan2
- ANKRD34B | c.409C>A p.L137I | Missense Mutation (SNP) | VAF 104/319 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV58614269; called by muse, mutect2, varscan2
- ANKRD44 | c.2436-1G>T p.X812_splice | Splice Site (SNP) | VAF 29/115 reads (25%) | catalogued as COSV99983921; called by muse, mutect2, varscan2
- ANKRD50 | c.2209C>T p.R737* | Nonsense Mutation (SNP) | VAF 30/85 reads (35%) | catalogued as COSV101538877, COSV72385130; called by muse, mutect2, varscan2
- ANKRD50 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as rs763266709, COSV72385175; called by muse, mutect2, varscan2
- ANKRD7 | c.529C>A p.L177I | Missense Mutation (SNP) | VAF 113/343 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99500895; called by muse, mutect2, varscan2
- ANKS6 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1221413415, COSV62051210; called by muse, mutect2
- ANKZF1 | c.2113G>A p.D705N | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1334953246, COSV55477330; called by muse, mutect2, varscan2
- ANO4 | c.397G>T p.E133* (on ENST00000392977 / NM_001286615.2; = p.E98* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 76/197 reads (39%) | catalogued as COSV100151725; called by muse, mutect2, varscan2
- ANO4 | c.2807T>C p.L936P (on ENST00000392977 / NM_001286615.2; = p.L901P on NM_178826.4) | Missense Mutation (SNP) | VAF 73/282 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100151726; called by muse, mutect2, varscan2
- ANPEP | c.2132G>A p.R711H | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.513); catalogued as rs182672249; called by muse, mutect2, varscan2
- ANTXR1 | c.818C>A p.S273Y | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as rs747143387, COSV58023545; called by mutect2, varscan2
- ANXA2 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs753106303, COSV100221852; called by muse, mutect2, varscan2
- ANXA4 | c.680A>C p.K227T | Missense Mutation (SNP) | VAF 105/445 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.782); catalogued as COSV101268756; called by muse, mutect2, varscan2
- ANXA8 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 61/1178 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1255805570; called by muse, mutect2
- AOAH | c.1067G>T p.R356I | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99334042; called by muse, mutect2, varscan2
- AOC3 | c.1336G>T p.D446Y | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV99519917; called by muse, varscan2
- AOX1 | c.3077C>T p.A1026V | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV99613342; called by muse, mutect2, varscan2
- AP001781.2 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 21/93 reads (23%) | catalogued as COSV52791546; called by muse, mutect2, varscan2
- AP1AR | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 99/369 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as rs367798505; called by muse, mutect2, varscan2
- AP1G2 | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as COSV99846050; called by muse, mutect2, varscan2
- AP3B1 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1474612691, COSV99670589, COSV99671381; called by muse, mutect2, varscan2
- AP4B1 | c.947A>C p.K316T | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99870502; called by muse, mutect2, varscan2
- AP5M1 | c.403C>A p.L135I | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as rs368987446; called by muse, mutect2, varscan2
- APAF1 | c.2339G>T p.S780I (on ENST00000551964 / NM_181861.2; = p.S769I on NM_001160.3) | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100452254; called by muse, mutect2, varscan2
- APAF1 | c.2595G>A p.E865= (on ENST00000551964 / NM_181861.2; = p.E854= on NM_013229.3) | Splice Region (SNP) | VAF 77/220 reads (35%) | catalogued as rs1480823721, COSV100452255; called by muse, mutect2, varscan2
- APC | c.446A>G p.D149G | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as CM107876; called by muse, mutect2, varscan2
- APC | c.3925G>T p.E1309* | Nonsense Mutation (SNP) | VAF 50/193 reads (26%) | catalogued as rs1321583762, CD084022, CD941590, CM920052, COSV57321386, COSV57334587, COSV99971982; called by muse, mutect2, varscan2
- APC | c.6086C>A p.S2029Y | Missense Mutation (SNP) | VAF 72/302 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99964923, COSV99964952; called by muse, mutect2, varscan2
- APCDD1 | c.120G>T p.E40D | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs149564774; called by muse, mutect2, varscan2
- APCDD1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.576); catalogued as rs771909445, COSV62372830; called by muse, mutect2, varscan2
- APH1B | c.741G>T p.K247N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.738); catalogued as rs748873773; called by muse, mutect2, varscan2
- APLP1 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.154); catalogued as rs763547342, COSV55702120; called by muse, mutect2, varscan2
- APMAP | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99468116; called by muse, mutect2, varscan2
- APOA2 | c.258C>A p.F86L | Missense Mutation (SNP) | VAF 70/309 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.019); catalogued as COSV99248074; called by muse, mutect2, varscan2
- APOL3 | c.938G>A p.R313Q (on ENST00000349314 / NM_145640.2; = p.R242Q on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs773872410, COSV62580362; called by muse, mutect2, varscan2
- AQP3 | c.483C>A p.F161L | Missense Mutation (SNP) | VAF 143/213 reads (67%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99955472; called by muse, mutect2, varscan2
- AQR | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV99333069; called by muse, mutect2, varscan2
- AR | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.706); catalogued as rs750324117, CM035613, COSV65953437, COSV65963147; called by muse, mutect2, varscan2
- ARAP1 | c.2150G>A p.R717Q (on ENST00000393609 / NM_001040118.2; = p.R472Q on NM_015242.4) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.083); catalogued as rs778301113, COSV100501502; called by muse, mutect2, varscan2
- ARAP2 | c.1280G>T p.R427I | Missense Mutation (SNP) | VAF 62/217 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV100394047, COSV58292047; called by muse, mutect2, varscan2
- ARCN1 | c.1198G>T p.D400Y | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV50615041, COSV99873380; called by muse, mutect2, varscan2
- ARFGEF1 | c.2107G>T p.E703* | Nonsense Mutation (SNP) | VAF 99/322 reads (31%) | catalogued as COSV99141048, COSV99144661; called by muse, mutect2, varscan2
- ARFGEF2 | c.4828C>T p.H1610Y | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs995799318, COSV64213598; called by muse, mutect2, varscan2
- ARFGEF3 | c.2584C>T p.R862C | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759459619, COSV99292157; called by muse, mutect2, varscan2
- ARHGAP11A | c.2453C>A p.S818Y | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100276645; called by muse, mutect2, varscan2
- ARHGAP21 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs995838696, COSV100255684; called by muse, mutect2, varscan2
- ARHGAP22 | c.1938G>T p.K646N | Missense Mutation (SNP) | VAF 169/459 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV50940567, COSV50970444; called by muse, mutect2, varscan2
- ARHGAP31 | c.881+1G>T p.X294_splice | Splice Site (SNP) | VAF 17/62 reads (27%) | catalogued as COSV99956474; called by muse, mutect2, varscan2
- ARHGAP31 | c.2211G>T p.E737D | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.111); catalogued as COSV99956477; called by muse, mutect2, varscan2
- ARHGAP9 | c.1504C>T p.R502W (on ENST00000393797 / NM_001319850.2; = p.R483W on NM_032496.4) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV99953631; called by mutect2, varscan2
- ARHGEF1 | c.99C>G p.N33K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV100528831, COSV100529194; called by muse, mutect2
- ARHGEF10 | c.3347C>T p.A1116V (on ENST00000398564; = p.A1091V on NM_014629.4) | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs769153898, COSV100033639; called by muse, mutect2, varscan2
- ARHGEF26 | c.2115T>G p.D705E | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62852835; called by muse, mutect2, varscan2
- ARHGEF3 | c.1429C>A p.L477I | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.013); catalogued as COSV99574856; called by muse, mutect2, varscan2
- ARHGEF3 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs776506559, COSV56324378; called by muse, mutect2, varscan2
- ARHGEF37 | c.1117C>T p.R373W | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs369500713; called by muse, mutect2, varscan2
- ARHGEF37 | c.2024C>A p.S675Y | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV100381869; called by muse, mutect2, varscan2
- ARHGEF4 | c.1585A>G p.I529V | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV100387518; called by muse, mutect2, varscan2
- ARID1B | c.3250C>T p.P1084S | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs746686035, COSV99266836; called by muse, mutect2, varscan2
- ARID2 | c.1700T>G p.F567C | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100535307; called by muse, mutect2, varscan2
- ARID4A | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 55/168 reads (33%) | catalogued as rs375498932; called by muse, varscan2
- ARL6IP5 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99832907; called by muse, mutect2, varscan2
- ARMC2 | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 76/291 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100933444; called by muse, mutect2, varscan2
- ARMC3 | c.362-1G>T p.X121_splice | Splice Site (SNP) | VAF 22/67 reads (33%) | catalogued as COSV99957375; called by muse, mutect2, varscan2
- ARMC4 | c.2557G>T p.D853Y | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV100536247; called by muse, mutect2, varscan2
- ARMC5 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51658619; called by muse, mutect2, varscan2
- ARMH4 | c.1629G>T p.M543I | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99957523; called by muse, varscan2
- ARMT1 | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.139); catalogued as rs560894715, COSV100939733; called by muse, mutect2, varscan2
- ARRDC3 | c.1009T>G p.L337V | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99475139; called by muse, varscan2
- ARRDC5 | c.487G>T p.E163* (on ENST00000381781; = p.E149* on NM_001080523.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/140 reads (22%) | catalogued as COSV101108073; called by muse, mutect2, varscan2
- ARSJ | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 115/328 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs756542116, COSV59537244; called by muse, mutect2, varscan2
- ARSL | c.1097A>G p.Q366R | Missense Mutation (SNP) | VAF 81/117 reads (69%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as COSV101140381; called by muse, mutect2, varscan2
- ART3 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.687); catalogued as rs776884042, COSV100587504; called by muse, mutect2, varscan2
- ARV1 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV59617445; called by muse, mutect2
- ASB5 | c.631T>C p.S211P | Missense Mutation (SNP) | VAF 103/272 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as COSV99641189, COSV99641368; called by muse, varscan2
- ASB5 | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99641193; called by muse, mutect2, varscan2
- ASB5 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 79/247 reads (32%) | catalogued as rs370097719; called by muse, mutect2, varscan2
- ASCC3 | c.6409C>T p.R2137* | Nonsense Mutation (SNP) | VAF 68/213 reads (32%) | catalogued as rs760927168, COSV64973923, COSV64977816; called by muse, mutect2, varscan2
- ASF1A | c.520C>A p.L174I | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.231); catalogued as COSV99995709; called by muse, mutect2, varscan2
- ASH1L | c.7123C>T p.R2375C (on ENST00000368346 / NM_001366177.2; = p.R2370C on NM_018489.3) | Missense Mutation (SNP) | VAF 129/418 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.386); catalogued as COSV64212393; called by muse, mutect2, varscan2
- ASH1L | c.6841C>T p.R2281* (on ENST00000368346 / NM_001366177.2; = p.R2276* on NM_018489.3) | Nonsense Mutation (SNP) | VAF 42/247 reads (17%) | catalogued as COSV64210367; called by muse, mutect2, varscan2
- ASH1L | c.3904C>T p.R1302W | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs746450493, COSV64210433; called by muse, mutect2, varscan2
- ASH2L | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1342895894, COSV51698982; called by muse, mutect2
- ASPA | c.596T>G p.I199S | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV99559122; called by muse, mutect2, varscan2
- ASPM | c.5537C>A p.S1846Y | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.746); catalogued as rs1334242199, COSV54125325, COSV99659410; called by muse, mutect2, varscan2
- ASTN1 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs760442147, COSV56061330; called by muse, mutect2, varscan2
- ASXL2 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 75/290 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs781524282, COSV55455671; called by muse, mutect2, varscan2
- ASXL2 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 96/137 reads (70%) | catalogued as COSV55453991, COSV55459868; called by muse, mutect2, varscan2
- ASXL3 | c.933C>A p.F311L | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52465157; called by muse, mutect2
- ATAD2B | c.3350G>T p.R1117I | Missense Mutation (SNP) | VAF 60/281 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.211); catalogued as COSV99476886; called by muse, mutect2, varscan2
- ATAT1 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV99527673; called by muse, mutect2, varscan2
- ATG5 | c.793C>A p.L265I | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.609); catalogued as COSV100576377; called by muse, mutect2, varscan2
- ATG5 | c.16G>T p.D6Y | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100576378; called by muse, mutect2, varscan2
- ATM | c.2464T>G p.L822V | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.206); catalogued as CD961797, COSV99587039; called by muse, mutect2, varscan2
- ATM | c.8026G>T p.E2676* | Nonsense Mutation (SNP) | VAF 33/139 reads (24%) | catalogued as COSV53770339; called by muse, mutect2, varscan2
- ATP10A | c.4061C>T p.S1354F | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV100791420; called by muse, mutect2
- ATP10A | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 10/126 reads (8%) | catalogued as COSV63514881; called by muse, mutect2
- ATP10D | c.1110T>G p.F370L | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as COSV99905077; called by muse, mutect2
- ATP11A | c.1912C>T p.R638* | Nonsense Mutation (SNP) | VAF 28/136 reads (21%) | catalogued as rs766879340, COSV52126969, COSV52127931; called by muse, mutect2, varscan2
- ATP11C | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 38/66 reads (58%) | catalogued as COSV100557258; called by muse, mutect2, varscan2
- ATP12A | c.204G>T p.E68D | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV99516917; called by muse, mutect2, varscan2
- ATP12A | c.2555G>A p.R852H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs768185894, COSV99516920; called by muse, mutect2
- ATP13A5 | c.2254G>T p.E752* | Nonsense Mutation (SNP) | VAF 47/149 reads (32%) | catalogued as rs1352082779, COSV60866463; called by muse, mutect2, varscan2
- ATP13A5 | c.1675-1G>A p.X559_splice | Splice Site (SNP) | VAF 34/118 reads (29%) | catalogued as COSV100664814, COSV60869073; called by muse, mutect2, varscan2
- ATP1B4 | c.1066G>T p.E356* (on ENST00000218008 / NM_001142447.3; = p.E352* on NM_012069.5) | Nonsense Mutation (SNP) | VAF 27/54 reads (50%) | catalogued as COSV99486105; called by muse, mutect2, varscan2
- ATP2A2 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 21/46 reads (46%) | catalogued as CM132883, COSV58046094; called by muse, mutect2, varscan2
- ATP2C1 | c.2710A>C p.K904Q | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV100146209; called by muse, mutect2, varscan2
- ATP4A | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as COSV52865717; called by muse, mutect2, varscan2
- ATP5MF | c.275A>C p.K92T | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV99461547; called by muse, mutect2, varscan2
- ATP6V0D2 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 27/56 reads (48%) | catalogued as COSV53416446; called by muse, mutect2, varscan2
- ATP6V1A | c.1632G>A p.M544I | Missense Mutation (SNP) | VAF 52/189 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99849788; called by muse, mutect2, varscan2
- ATP6V1C1 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as rs772801674, COSV101214809; called by muse, mutect2, varscan2
- ATP8B4 | c.1344C>A p.F448L | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99463360; called by muse, varscan2
- ATP9A | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as rs781681734, COSV100124247; called by muse, varscan2
- ATR | c.4940G>A p.R1647H | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as rs758322712, COSV63383741; called by muse, mutect2, varscan2
- ATR | c.3044G>A p.R1015Q | Missense Mutation (SNP) | VAF 64/352 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.372); catalogued as rs564283952, COSV63385583, COSV63386951; called by muse, mutect2, varscan2
- ATRN | c.4115T>G p.F1372C | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99496478; called by muse, mutect2, varscan2
- ATRNL1 | c.3746C>T p.A1249V | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100369186; called by muse, mutect2, varscan2
- ATRX | c.4749G>T p.K1583N | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.223); catalogued as COSV64885610; called by muse, mutect2, varscan2
- ATRX | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV64877356; called by muse, mutect2, varscan2
- ATRX | c.1162A>C p.K388Q | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); catalogued as COSV64885620; called by muse, mutect2, varscan2
- AUH | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs141700491; called by muse, mutect2, varscan2
- AURKC | c.408G>T p.E136D (on ENST00000302804 / NM_001015878.2; = p.E102D on NM_003160.3) | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100248693; called by muse, mutect2, varscan2
- AXL | c.349T>C p.C117R | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781434711, COSV99995805; called by muse, mutect2, varscan2
- AXL | c.2120G>A p.R707H (on ENST00000301178 / NM_021913.5; = p.R698H on NM_001699.6) | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs773403341, COSV99995808; called by muse, mutect2, varscan2
- AZIN1 | c.748C>A p.H250N | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100457317; called by muse, mutect2, varscan2
- B3GALNT1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs752083614, COSV57581127; called by muse, mutect2, varscan2
- B3GLCT | c.833A>C p.K278T | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100587083; called by muse, mutect2, varscan2
- B3GLCT | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58454166; called by muse, varscan2
- B3GNT5 | c.565C>A p.L189I | Missense Mutation (SNP) | VAF 81/218 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV58475736; called by muse, mutect2, varscan2
- B4GALT6 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 19/82 reads (23%) | catalogued as COSV52702410; called by muse, mutect2, varscan2
- BACH1 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.058); catalogued as COSV99727883; called by muse, mutect2, varscan2
- BAG4 | c.1000C>A p.L334I | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.146); catalogued as COSV54860611; called by muse, mutect2, varscan2
- BAHD1 | c.2088G>T p.Q696H | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101346709; called by muse, mutect2, varscan2
- BAIAP2L1 | c.70A>G p.N24D | Missense Mutation (SNP) | VAF 73/332 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99133603; called by muse, mutect2, varscan2
- BANK1 | c.189G>T p.E63D | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.21); catalogued as COSV100535789; called by muse, mutect2
- BANK1 | c.1070A>G p.N357S | Missense Mutation (SNP) | VAF 144/369 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100535790; called by muse, varscan2
- BATF2 | c.643A>G p.T215A | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100101670; called by muse, mutect2, varscan2
- BBS9 | c.2330C>T p.S777F (on ENST00000242067 / NM_001348036.1; = p.S737F on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99625690; called by muse, mutect2, varscan2
- BCAS1 | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV101006005; called by muse, mutect2, varscan2
- BCAS3 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101175018; called by muse, mutect2, varscan2
- BCCIP | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 13/113 reads (12%) | catalogued as COSV99532851; called by muse, mutect2, varscan2
- BCDIN3D | c.458T>G p.F153C | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.635); catalogued as COSV100445432; called by muse, mutect2, varscan2
- BCHE | c.77C>A p.S26* | Nonsense Mutation (SNP) | VAF 30/122 reads (25%) | catalogued as COSV100012047; called by muse, mutect2, varscan2
- BCL11B | c.2674G>A p.E892K (on ENST00000357195 / NM_001282237.2; = p.E821K on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.229); catalogued as rs1187414703, COSV61735334; called by muse, mutect2, varscan2
- BCL9 | c.2979T>G p.Y993* | Nonsense Mutation (SNP) | VAF 24/127 reads (19%) | catalogued as COSV99324393; called by muse, mutect2, varscan2
- BCLAF1 | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.204); catalogued as COSV100786801, COSV62140883, COSV62146597; called by mutect2, varscan2
- BEST3 | c.843C>A p.F281L | Missense Mutation (SNP) | VAF 67/210 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs745673258, COSV58299229, COSV58299561; called by muse, mutect2, varscan2
- BHLHE41 | c.55T>G p.F19V | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as COSV54378479; called by muse, mutect2
- BHMT2 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs141648685, COSV54874678; called by muse, mutect2, varscan2
- BICDL1 | c.798G>T p.E266D | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101287131; called by muse, mutect2, varscan2
- BIRC6 | c.14548G>T p.E4850* | Nonsense Mutation (SNP) | VAF 35/90 reads (39%) | catalogued as COSV70202505; called by muse, mutect2, varscan2
- BLM | c.3755C>T p.S1252F | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100756882, COSV61923990; called by muse, mutect2, varscan2
- BMP10 | c.824C>A p.S275Y | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV99770254; called by muse, mutect2, varscan2
- BMP7 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV67779434; called by muse, mutect2, varscan2
- BMP7 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV101215390; called by muse, mutect2, varscan2
- BMPER | c.1421C>A p.S474Y | Missense Mutation (SNP) | VAF 118/326 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV99778780; called by muse, mutect2, varscan2
- BMS1 | c.1567G>T p.E523* | Nonsense Mutation (SNP) | VAF 42/138 reads (30%) | catalogued as COSV100996430; called by muse, varscan2
- BMS1 | c.1673G>T p.S558I | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.054); catalogued as rs1284854699, COSV100996432; called by muse, varscan2
- BNC1 | c.2339G>A p.S780N | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100596875; called by muse, mutect2, varscan2
- BNC1 | c.929C>G p.A310G | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100596877; called by muse, mutect2, varscan2
- BNC2 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773045476, COSV66142375; called by muse, mutect2, varscan2
- BPIFB4 | c.1095C>A p.F365L | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV100971403; called by muse, mutect2, varscan2
- BPIFB6 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 50/199 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as rs750762957, COSV100848475; called by muse, mutect2, varscan2
- BPTF | c.8161C>T p.R2721C | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100073904; called by muse, mutect2, varscan2
- BRCA2 | c.4690G>A p.A1564T | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.031); catalogued as COSV66464702; called by muse, mutect2
- BRD1 | c.3037G>A p.E1013K (on ENST00000216267 / NM_001349940.1; = p.E1144K on NM_001304808.3) | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs1046139158, COSV53462584; called by muse, mutect2, varscan2
- BRINP3 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV66513604, COSV66513646; called by muse, mutect2, varscan2
- BRIP1 | c.3386C>A p.S1129Y | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99369113, COSV99371073; called by muse, mutect2, varscan2
- BRIX1 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 29/311 reads (9%) | catalogued as COSV59130663; called by muse, mutect2
- BRSK1 | c.204G>T p.E68D | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.669); catalogued as COSV100510259; called by muse, mutect2, varscan2
- BRSK1 | c.1044G>T p.K348N | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100473606; called by muse, mutect2, varscan2
- BRWD1 | c.4852C>A p.L1618I | Missense Mutation (SNP) | VAF 75/232 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100312693; called by muse, mutect2, varscan2
- BTAF1 | c.2318G>A p.R773Q | Missense Mutation (SNP) | VAF 83/244 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs992826231, COSV99794822; called by muse, mutect2, varscan2
- BTBD10 | c.62A>C p.K21T | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99533298; called by muse, mutect2, varscan2
- BTBD11 | c.3109C>A p.L1037I (on ENST00000280758 / NM_001018072.2; = p.L574I on NM_001017523.2) | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.978); catalogued as COSV55022832; called by muse, mutect2, varscan2
- BTK | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs782338603, COSV58117157; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTRC | c.824T>G p.I275S (on ENST00000370187 / NM_033637.4; = p.I239S on NM_003939.5) | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100927696; called by muse, mutect2, varscan2
- C12orf42 | c.167G>T p.R56I | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV59386810; called by muse, varscan2
- C12orf54 | c.207C>A p.C69* | Nonsense Mutation (SNP) | VAF 34/91 reads (37%) | catalogued as COSV100011496; called by muse, mutect2, varscan2
- C14orf39 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0.319); catalogued as COSV100407194, COSV58780117; called by muse, mutect2, varscan2
- C16orf71 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as rs144417396, COSV54794707; called by muse, mutect2, varscan2
- C18orf25 | c.1031T>C p.V344A | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV56365093; called by muse, mutect2
- C1orf112 | c.843A>G p.I281M | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as COSV99609331; called by muse, mutect2, varscan2
- C1orf127 | c.980G>A p.C327Y | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV65439578; called by muse, mutect2, varscan2
- C20orf194 | c.1712T>G p.F571C | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99330189; called by muse, mutect2, varscan2
- C20orf194 | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 49/126 reads (39%) | catalogued as COSV99330190; called by muse, mutect2, varscan2
- C20orf194 | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 27/90 reads (30%) | catalogued as COSV52699229; called by muse, mutect2, varscan2
- C21orf62 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs148054755, COSV66672227; called by muse, mutect2, varscan2
- C2CD5 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV61723360; called by muse, mutect2, varscan2
- C2orf80 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 48/288 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.275); catalogued as rs751832381; called by muse, mutect2, varscan2
- C3orf20 | c.2330C>A p.S777Y | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV99513315; called by muse, mutect2, varscan2
- C3orf33 | c.871C>T p.R291C (on ENST00000340171 / NM_001308229.2; = p.R248C on NM_173657.2) | Missense Mutation (SNP) | VAF 88/239 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs200965203; called by muse, mutect2, varscan2
- C3orf33 | c.274G>T p.E92* (on ENST00000340171 / NM_001308229.2; = p.E49* on NM_173657.2) | Nonsense Mutation (SNP) | VAF 14/258 reads (5%) | catalogued as COSV60896343; called by muse, mutect2
- C6orf58 | c.935C>A p.S312Y | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.018); catalogued as COSV100314661; called by muse, mutect2, varscan2
- C6orf89 | c.619G>T p.E207* (on ENST00000373685; = p.E214* on NM_152734.4) | Nonsense Mutation (SNP) | VAF 106/160 reads (66%) | catalogued as COSV100769662; called by muse, varscan2
- C7orf25 | c.826C>T p.L276F | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100623592; called by muse, mutect2, varscan2
- C7orf57 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs373360459; called by mutect2, varscan2
- C8orf74 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs572694662, COSV58753873; called by mutect2, varscan2
- CABIN1 | c.4565G>A p.R1522H | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1569243251, COSV54077629; called by muse, mutect2, varscan2
- CACHD1 | c.2312C>A p.S771Y | Missense Mutation (SNP) | VAF 79/230 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV99261328; called by muse, mutect2, varscan2
- CACNA1E | c.2234C>T p.S745L | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.086); catalogued as rs776757923, COSV62406537; called by muse, mutect2, varscan2
- CACNA1E | c.5810C>T p.S1937L | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as rs1007685928, COSV62383196; called by muse, mutect2
- CACNA1G | c.4301T>C p.F1434S | Missense Mutation (SNP) | VAF 49/270 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61742083; called by muse, mutect2, varscan2
- CACNA1G | c.4915C>A p.L1639M | Missense Mutation (SNP) | VAF 44/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61742101; called by muse, mutect2, varscan2
- CACNA1S | c.1450T>C p.Y484H | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100754597; called by muse, mutect2, varscan2
- CACNA2D3 | c.1846T>G p.L616V | Missense Mutation (SNP) | VAF 76/302 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV99869741; called by muse, mutect2, varscan2
- CACNA2D4 | c.1823T>G p.I608S | Missense Mutation (SNP) | VAF 107/359 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV54963620; called by muse, mutect2, varscan2
- CAD | c.3142C>T p.R1048C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1372902996, COSV99254340; called by muse, mutect2, varscan2
- CADPS2 | c.3736C>T p.R1246* | Nonsense Mutation (SNP) | VAF 27/83 reads (33%) | catalogued as rs1354028382, COSV57349948, COSV57350326; called by muse, mutect2, varscan2
- CADPS2 | c.1090T>C p.S364P | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100460571; called by muse, varscan2
- CALD1 | c.1494C>A p.F498L (on ENST00000361675 / NM_033138.4; = p.F243L on NM_004342.7) | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV100723983, COSV62649842; called by muse, mutect2, varscan2
- CALHM5 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.116); catalogued as rs539288012, COSV100635512; called by muse, mutect2, varscan2
- CALM1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as COSV63662962, COSV63663711; called by muse, mutect2
- CALML4 | c.388C>A p.L130I | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); catalogued as COSV100682811; called by muse, mutect2
- CAMSAP1 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 20/279 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV56719922; called by muse, mutect2
- CAMSAP3 | c.3418G>A p.E1140K | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV50335313, COSV99350041; called by muse, mutect2, varscan2
- CAPN5 | c.1297G>A p.E433K (on ENST00000456580; = p.E393K on NM_004055.5) | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs369845664; called by muse, mutect2, varscan2
- CARD8 | c.982G>A p.E328K (on ENST00000651546 / NM_001184900.3; = p.E278K on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/247 reads (35%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.989); catalogued as rs758242862, COSV62872805; called by muse, mutect2, varscan2
- CARMIL1 | c.2896C>T p.R966W | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs763392762, COSV61520503; called by muse, mutect2, varscan2
- CARNMT1 | c.869C>A p.S290Y | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100961620; called by muse, varscan2
- CARNMT1 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV65194572; called by muse, mutect2, varscan2
- CASP1 | c.804G>T p.K268N (on ENST00000436863 / NM_033292.4; = p.K247N on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/368 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as rs202211771, COSV100782707; called by muse, mutect2, varscan2
- CASP14 | c.598G>T p.G200* | Nonsense Mutation (SNP) | VAF 50/147 reads (34%) | catalogued as COSV99692884; called by muse, mutect2, varscan2
- CASP5 | c.860T>G p.L287R | Missense Mutation (SNP) | VAF 130/345 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.03); catalogued as COSV99507108; called by muse, mutect2, varscan2
- CASR | c.365C>A p.S122Y | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.959); catalogued as rs778201006, CM1310392, COSV56134103; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASR | c.1232A>G p.Y411C | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.854); catalogued as COSV99948401; called by muse, mutect2, varscan2
- CASR | c.1595C>T p.T532M (on ENST00000490131; = p.T609M on NM_000388.4) | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.897); catalogued as rs759904153, COSV99948403; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAST | c.577G>T p.E193* (on ENST00000341926; = p.E276* on NM_001750.7 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 193/510 reads (38%) | catalogued as COSV100352128; called by muse, mutect2, varscan2
- CASTOR1 | c.681C>A p.F227L | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV57577180; called by muse, mutect2, varscan2
- CATSPERB | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs768019574, COSV56434429; called by muse, mutect2, varscan2
- CAVIN3 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV58269730; called by muse, mutect2
- CBFA2T2 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs146788442; called by muse, mutect2, varscan2
- CBX3 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 65/268 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs1208793747, COSV61761621; called by muse, mutect2, varscan2
- CCDC110 | c.1921A>C p.K641Q | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100293627; called by muse, varscan2
- CCDC137 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as rs1183118474; called by muse, mutect2, varscan2
- CCDC138 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 60/296 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs896059293, COSV54567061; called by muse, varscan2
- CCDC14 | c.2451G>T p.K817N (on ENST00000488653; = p.K769N on NM_022757.5) | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as COSV100112911, COSV59947443; called by muse, mutect2, varscan2
- CCDC14 | c.1082G>T p.R361I (on ENST00000488653; = p.R313I on NM_022757.5) | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.134); catalogued as rs377682889; called by muse, mutect2, varscan2
- CCDC141 | c.3787G>A p.E1263K | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as rs1212530049, COSV55379281; called by muse, mutect2, varscan2
- CCDC141 | c.2754G>T p.K918N | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376518328; called by muse, mutect2, varscan2
- CCDC144A | c.1394A>G p.N465S | Missense Mutation (SNP) | VAF 362/1647 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100138284; called by muse, mutect2, varscan2
- CCDC144A | c.3158G>A p.R1053Q | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.101); catalogued as rs199644397; called by muse, varscan2
- CCDC146 | c.1521T>G p.I507M | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as COSV99592080; called by muse, mutect2, varscan2
- CCDC15 | c.2397G>T p.K799N | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs764907206, COSV61080185; called by muse, mutect2, varscan2
- CCDC158 | c.305A>C p.E102A | Missense Mutation (SNP) | VAF 98/286 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV101187137; called by muse, varscan2
- CCDC171 | c.2718G>T p.K906N | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV52633945, COSV99899566; called by muse, mutect2
- CCDC171 | c.3514G>T p.D1172Y | Missense Mutation (SNP) | VAF 14/243 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs896927475, COSV52655502; called by muse, mutect2
- CCDC18 | c.1507G>T p.D503Y (on ENST00000343253 / NM_001306076.1; = p.D504Y on NM_206886.4) | Missense Mutation (SNP) | VAF 98/269 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58147381; called by muse, mutect2, varscan2
- CCDC180 | c.3047C>A p.S1016* | Nonsense Mutation (SNP) | VAF 33/133 reads (25%) | catalogued as COSV63832688; called by muse, mutect2, varscan2
- CCDC181 | c.601C>A p.L201I | Missense Mutation (SNP) | VAF 81/212 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as COSV100890231; called by muse, mutect2, varscan2
- CCDC186 | c.346A>G p.T116A | Missense Mutation (SNP) | VAF 163/477 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.124); catalogued as COSV100990979; called by muse, mutect2, varscan2
- CCDC191 | c.467T>G p.F156C | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1031780972, COSV55672221; called by muse, mutect2, varscan2
- CCDC198 | c.299G>T p.R100I | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53601250; called by muse, mutect2, varscan2
- CCDC28A | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 19/36 reads (53%) | catalogued as COSV100236236; called by muse, mutect2, varscan2
- CCDC34 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 126/808 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.98); catalogued as rs772307472, COSV58727391; called by muse, mutect2, varscan2
- CCDC39 | c.2738C>T p.A913V | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.055); catalogued as COSV99866987; called by muse, mutect2, varscan2
- CCDC39 | c.2293G>T p.E765* | Nonsense Mutation (SNP) | VAF 43/113 reads (38%) | catalogued as rs1282693527, COSV99866991; called by muse, mutect2, varscan2
- CCDC39 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56477668, COSV99867362; called by muse, mutect2, varscan2
- CCDC54 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 48/197 reads (24%) | catalogued as COSV53758671; called by muse, mutect2, varscan2
- CCDC63 | c.953A>G p.N318S | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as COSV100370155; called by muse, mutect2, varscan2
- CCDC7 | c.3072C>A p.F1024L | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.897); catalogued as COSV100177350; called by muse, mutect2, varscan2
- CCDC73 | c.1438A>C p.N480H | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.794); catalogued as COSV100066342; called by muse, mutect2
- CCDC8 | c.1417A>G p.K473E | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV100281849; called by muse, mutect2, varscan2
- CCDC80 | c.2455T>A p.L819I | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.444); catalogued as COSV99244179; called by muse, mutect2, varscan2
- CCDC83 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.067); catalogued as rs553174518, COSV54700993, COSV54703567; called by muse, mutect2, varscan2
- CCDC88A | c.4051C>A p.L1351I | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.719); catalogued as COSV99709694; called by muse, mutect2, varscan2
- CCDC88A | c.2760G>T p.Q920H | Missense Mutation (SNP) | VAF 109/323 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99709697; called by muse, mutect2, varscan2
- CCDC92 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as rs1460952697, COSV53019580; called by muse, mutect2, varscan2
- CCKBR | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1431400028, COSV58099764; called by muse, mutect2, varscan2
- CCL27 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.217); catalogued as COSV99426383; called by muse, mutect2, varscan2
- CCN6 | c.516G>T p.K172N | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100036884, COSV57890769; called by muse, mutect2, varscan2
- CCN6 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 95/343 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs140750750, COSV57888796; ClinVar: uncertain significance; called by muse, varscan2
- CCNH | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.209); catalogued as rs1282114823, COSV56926026; called by muse, mutect2, varscan2
- CCNT2 | c.1439C>A p.S480Y | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV51474722; called by muse, mutect2
- CCPG1 | c.2199C>A p.F733L | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.488); catalogued as rs776958605, COSV99379977; called by muse, mutect2, varscan2
- CCSER1 | c.399G>T p.E133D | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.137); catalogued as COSV61420796; called by muse, mutect2, varscan2
- CCSER2 | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 40/127 reads (31%) | catalogued as COSV56501827; called by muse, mutect2, varscan2
- CCT8L2 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100742544; called by muse, mutect2, varscan2
- CCZ1B | c.725G>T p.R242I | Missense Mutation (SNP) | VAF 16/348 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100367706, COSV57438014; called by muse, mutect2
- CD101 | c.1618A>C p.S540R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.853); catalogued as COSV99869056; called by muse, mutect2, varscan2
- CD109 | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99752440; called by muse, mutect2, varscan2
- CD109 | c.862G>T p.G288* | Nonsense Mutation (SNP) | VAF 16/71 reads (23%) | catalogued as rs765239774, COSV99752445; called by muse, mutect2, varscan2
- CD109 | c.1876T>C p.F626L | Missense Mutation (SNP) | VAF 78/341 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99752449; called by muse, varscan2
- CD109 | c.3977T>C p.V1326A | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV99752451; called by muse, mutect2, varscan2
- CD163 | c.128C>A p.S43Y | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV63129992; called by muse, mutect2, varscan2
- CD163L1 | c.4218T>G p.N1406K | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.439); catalogued as COSV100549605; called by muse, mutect2
- CD163L1 | c.2270C>A p.S757Y | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT tolerated (1); PolyPhen probably damaging (0.972); catalogued as COSV58022993; called by muse, mutect2, varscan2
- CD209 | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV52659939; called by muse, mutect2, varscan2
- CD22 | c.2365G>T p.D789Y | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV99322779; called by muse, mutect2, varscan2
- CD300A | c.162G>T p.Q54H | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV60410352; called by muse, mutect2, varscan2
- CD300C | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as COSV100423162; called by muse, mutect2
- CD300E | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.186); catalogued as rs545591203, COSV60790732; called by muse, mutect2, varscan2
- CD46 | c.736T>A p.F246I | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM165481, COSV59735665; called by muse, varscan2
- CD46 | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 57/262 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100522703; called by muse, varscan2
- CD72 | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99427247; called by muse, mutect2
- CD84 | c.892G>T p.E298* (on ENST00000311224 / NM_001184879.2; = p.E281* on NM_003874.4) | Nonsense Mutation (SNP) | VAF 39/136 reads (29%) | catalogued as COSV100245777; called by muse, mutect2, varscan2
- CD93 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as rs762071141, COSV55669405, COSV99848760; called by muse, varscan2
- CDC42BPA | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62003520; called by muse, mutect2, varscan2
- CDC42EP3 | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99767745; called by muse, mutect2, varscan2
- CDC7 | c.1533T>G p.N511K | Missense Mutation (SNP) | VAF 72/211 reads (34%) | SIFT tolerated (0.89); PolyPhen benign (0.013); catalogued as COSV99319520; called by muse, mutect2, varscan2
- CDCA7L | c.376G>T p.D126Y | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV100650944, COSV62261312; called by muse, mutect2, varscan2
- CDH1 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs121964873, COSV55736787, COSV55737055; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH10 | c.2249C>A p.S750* | Nonsense Mutation (SNP) | VAF 35/134 reads (26%) | catalogued as COSV52571640, COSV52585324; called by muse, mutect2, varscan2
- CDH10 | c.1294T>G p.F432V | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100049904; called by muse, varscan2
- CDH10 | c.1238C>A p.S413Y | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as COSV100049907, COSV100050786; called by muse, mutect2, varscan2
- CDH10 | c.590G>A p.R197K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.067); catalogued as COSV100049909; called by muse, varscan2
- CDH10 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100049911; called by muse, mutect2, varscan2
- CDH11 | c.1364A>G p.N455S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs201146780, COSV99217010; called by muse, varscan2
- CDH12 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 52/198 reads (26%) | catalogued as COSV66387559; called by muse, mutect2, varscan2
- CDH18 | c.996G>T p.K332N | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV56903914; called by muse, varscan2
- CDH19 | c.153dup p.V52Cfs*9 | Frame Shift Ins (INS) | VAF 48/159 reads (30%) | catalogued as rs746163720; called by mutect2, pindel, varscan2
- CDH2 | c.2304T>G p.D768E | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99295517; called by muse, mutect2, varscan2
- CDH2 | c.1639G>T p.D547Y | Missense Mutation (SNP) | VAF 79/281 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52271407; called by muse, mutect2, varscan2
- CDH2 | c.1557C>A p.F519L | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as COSV99295519; called by muse, varscan2
- CDH20 | c.1482C>A p.F494L | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.029); catalogued as COSV53016850, COSV99404208; called by muse, mutect2, varscan2
- CDH23 | c.2158C>T p.R720W | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs746487992, COSV99818581; called by muse, mutect2, varscan2
- CDH23 | c.5143G>T p.D1715Y | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56463839, COSV99818587; called by muse, mutect2, varscan2
- CDH23 | c.10021C>T p.R3341C | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs370074117; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH26 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 133/731 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.067); catalogued as rs1479719725, COSV54847357; called by muse, mutect2, varscan2
- CDH6 | c.530T>G p.F177C | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV99417931; called by muse, mutect2, varscan2
- CDH8 | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 58/169 reads (34%) | catalogued as COSV100179393; called by muse, mutect2, varscan2
- CDH9 | c.1569C>A p.F523L | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV50330527, COSV99141382; called by muse, mutect2, varscan2
- CDH9 | c.811+2T>C p.X271_splice | Splice Site (SNP) | VAF 82/229 reads (36%) | catalogued as COSV99141385; called by muse, mutect2, varscan2
- CDH9 | c.154A>G p.K52E | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV99141391; called by muse, varscan2
- CDHR1 | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV100258346, COSV100259224; called by muse, mutect2, varscan2
- CDK13 | c.2520T>G p.C840W | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99474990; called by muse, mutect2, varscan2
- CDK4 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763652580, COSV56986143; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3106G>A p.D1036N | Missense Mutation (SNP) | VAF 74/236 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as COSV100575033; called by muse, mutect2, varscan2
- CDK7 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 178/629 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99841497; called by muse, mutect2, varscan2
- CDNF | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 80/239 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101012354; called by muse, varscan2
- CDR2 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs563641354; called by mutect2, varscan2
- CDRT1 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1327139893, COSV63052386, COSV63054528; called by muse, mutect2, varscan2
- CEACAM18 | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101140125; called by muse, mutect2, varscan2
- CEACAM18 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs267605617; called by muse, mutect2, varscan2
- CEBPZ | c.2087A>G p.Y696C | Missense Mutation (SNP) | VAF 43/396 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99304945; called by muse, mutect2, varscan2
- CELA2B | c.266A>G p.N89S | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV65545914; called by muse, mutect2
- CELF3 | c.1185G>T p.E395D | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.994); catalogued as COSV99309989; called by muse, mutect2, varscan2
- CEMIP | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs181470477, COSV99585950; called by muse, mutect2, varscan2
- CENPE | c.7668T>G p.I2556M | Missense Mutation (SNP) | VAF 157/415 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV54380847; called by muse, mutect2, varscan2
- CENPE | c.2356C>A p.H786N | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV99476853; called by muse, mutect2, varscan2
- CENPF | c.3147G>T p.K1049N | Missense Mutation (SNP) | VAF 101/272 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.139); catalogued as COSV65274818; called by muse, mutect2, varscan2
- CENPF | c.4227G>T p.E1409D | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV65273638; called by muse, mutect2, varscan2
- CENPF | c.8124G>T p.K2708N | Missense Mutation (SNP) | VAF 182/521 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as COSV100871470, COSV65278286; called by muse, mutect2, varscan2
- CEP112 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 151/642 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs549226002, COSV101210480; called by muse, mutect2, varscan2
- CEP128 | c.1839G>T p.E613D | Missense Mutation (SNP) | VAF 20/275 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV99823522; called by muse, mutect2
- CEP128 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 81/193 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.525); catalogued as rs573572660, COSV55383907; called by muse, mutect2, varscan2
- CEP152 | c.4576G>A p.D1526N (on ENST00000380950 / NM_001194998.2; = p.D1470N on NM_014985.4) | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.103); catalogued as rs577236018, COSV57856542; called by muse, mutect2, varscan2
- CEP152 | c.2960G>A p.R987Q | Missense Mutation (SNP) | VAF 104/496 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755071182, COSV57858956; called by muse, mutect2, varscan2
- CEP152 | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 13/170 reads (8%) | catalogued as COSV57858240; called by muse, mutect2
- CEP192 | c.7174G>A p.E2392K | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1298184979, COSV100380507; called by muse, mutect2, varscan2
- CEP290 | c.4990G>T p.E1664* | Nonsense Mutation (SNP) | VAF 54/191 reads (28%) | catalogued as COSV100467681; called by muse, mutect2, varscan2
- CEP70 | c.407G>T p.R136M | Missense Mutation (SNP) | VAF 126/405 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.155); catalogued as COSV99388775; called by muse, mutect2, varscan2
- CEP83 | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 76/368 reads (21%) | catalogued as rs1216945458, COSV60407553; called by muse, varscan2
- CEP83 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 110/272 reads (40%) | catalogued as COSV60407666, COSV60408122; called by muse, mutect2, varscan2
- CEP85L | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 113/338 reads (33%) | catalogued as rs752640404, COSV100874025; called by muse, mutect2, varscan2
- CEP95 | c.1988T>A p.I663N | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV73609713; called by muse, mutect2, varscan2
- CERKL | c.815G>T p.R272I (on ENST00000339098 / NM_001030311.2; = p.R246I on NM_201548.5) | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100183067, COSV59206395; called by muse, mutect2, varscan2
- CERS3 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752230253, COSV52567747; called by muse, mutect2, varscan2
- CES5A | c.1520C>A p.S507Y (on ENST00000290567 / NM_001143685.2; = p.S457Y on NM_145024.3) | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV51865594, COSV99307047; called by muse, mutect2, varscan2
- CFAP161 | c.711-1G>T p.X237_splice | Splice Site (SNP) | VAF 30/123 reads (24%) | catalogued as COSV99715355; called by muse, mutect2, varscan2
- CFAP206 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.131); catalogued as rs777448285, COSV51534027; called by mutect2, varscan2
- CFAP251 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 26/125 reads (21%) | catalogued as COSV99995665; called by muse, mutect2, varscan2
- CFAP251 | c.3025G>A p.E1009K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs776727712, COSV56608786; called by muse, mutect2, varscan2
- CFAP46 | c.6493C>T p.P2165S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as rs560086678, COSV99583847; called by muse, mutect2, varscan2
- CFAP47 | c.4439A>C p.E1480A | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.486); catalogued as COSV100544856; called by muse, mutect2, varscan2
- CFAP54 | c.5119G>T p.E1707* | Nonsense Mutation (SNP) | VAF 42/109 reads (39%) | catalogued as COSV61570456, COSV61570908; called by muse, mutect2, varscan2
- CFAP58 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as rs61732088; called by muse, mutect2, varscan2
- CFAP94 | c.1988C>A p.S663Y (on ENST00000320267 / NM_001352064.2; = p.S669Y on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100208869; called by muse, varscan2
- CFAP94 | c.1908G>T p.E636D (on ENST00000320267 / NM_001352064.2; = p.E642D on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100208870; called by muse, varscan2
- CFLAR | c.1143G>T p.K381N | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV100009049; called by muse, mutect2, varscan2
- CGN | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs751915500, COSV54969464, COSV99641828; called by muse, mutect2, varscan2
- CHAF1B | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.508); catalogued as rs759420528, COSV100023316; called by muse, mutect2, varscan2
- CHCHD6 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV99335591; called by muse, mutect2, varscan2
- CHD1 | c.4832G>T p.R1611M | Missense Mutation (SNP) | VAF 17/251 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV99399040; called by muse, mutect2
- CHD1 | c.3566G>A p.R1189Q | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV52336710; called by muse, mutect2, varscan2
- CHD4 | c.3241G>A p.E1081K (on ENST00000357008 / NM_001363606.2; = p.E1094K on NM_001273.5) | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV58894162; called by muse, mutect2, varscan2
- CHD5 | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV99312266; called by muse, mutect2, varscan2
- CHD7 | c.3535C>A p.Q1179K | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.627); catalogued as CM074742, COSV101417964; called by muse, mutect2, varscan2
- CHD9 | c.2046G>A p.E682= | Splice Region (SNP) | VAF 50/169 reads (30%) | catalogued as COSV101271848, COSV68297875; called by muse, mutect2, varscan2
- CHD9 | c.5670C>A p.F1890L | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99528653; called by muse, mutect2, varscan2
- CHD9 | c.7367C>A p.S2456Y (on ENST00000398510 / NM_001382353.1; = p.S2440Y on NM_025134.7) | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV99528654; called by muse, mutect2, varscan2
- CHD9 | c.8170C>A p.L2724M (on ENST00000398510 / NM_001382353.1; = p.L2708M on NM_025134.7) | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.986); catalogued as COSV54613377; called by muse, mutect2, varscan2
- CHIA | c.1390C>T p.L464F (on ENST00000343320; = p.L356F on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58478978; called by muse, mutect2, varscan2
- CHIC2 | c.137A>C p.K46T | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.903); catalogued as COSV55756504; called by muse, mutect2
- CHL1 | c.757C>A p.L253I (on ENST00000397491 / NM_001253387.1; = p.L269I on NM_006614.4) | Missense Mutation (SNP) | VAF 87/229 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.495); catalogued as COSV99849938; called by muse, mutect2, varscan2
- CHL1 | c.3160G>A p.D1054N (on ENST00000397491 / NM_001253387.1; = p.D1070N on NM_006614.4) | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs752896455, COSV56589298; called by muse, mutect2, varscan2
- CHMP3 | c.66G>T p.K22N | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV55686043; called by muse, varscan2
- CHMP7 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.051); catalogued as rs149875498; called by muse, mutect2, varscan2
- CHODL | c.611A>C p.Q204P | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as COSV100166564; called by muse, mutect2, varscan2
- CHRAC1 | c.207G>T p.K69N | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV99636066; called by muse, mutect2, varscan2
- CHRM2 | c.959C>A p.S320Y | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV100280647, COSV57768376, COSV57782619; called by muse, mutect2, varscan2
- CHRNA2 | c.630G>T p.K210N | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV99531859; called by muse, mutect2, varscan2
- CHRNB1 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV99548141; called by muse, mutect2, varscan2
- CHRNB2 | c.468G>T p.K156N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV100872525, COSV63808275, COSV63808363; called by muse, mutect2, varscan2
- CHRNB3 | c.1023G>T p.Q341H | Missense Mutation (SNP) | VAF 71/257 reads (28%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.946); catalogued as COSV99250835; called by muse, mutect2, varscan2
- CHST15 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753436566, COSV60560851; called by muse, mutect2, varscan2
- CHST15 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100654899, COSV60565823; called by muse, mutect2
- CHST9 | c.977C>A p.S326Y | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52450231, COSV52451894; called by muse, mutect2, varscan2
- CHSY3 | c.1857G>T p.K619N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs1297392868, COSV100518401, COSV59276872; called by muse, mutect2, varscan2
- CHSY3 | c.2095C>T p.L699F | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV100518402; called by muse, mutect2, varscan2
- CIBAR1 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV100844624; called by muse, varscan2
- CITED2 | c.682C>A p.L228I | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100863091; called by muse, mutect2, varscan2
- CKAP5 | c.271T>C p.S91P | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); catalogued as COSV100370329; called by muse, mutect2, varscan2
- CKS1B | c.15A>C p.Q5H | Missense Mutation (SNP) | VAF 93/240 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV100460337; called by muse, mutect2, varscan2
- CLASP1 | c.2420C>T p.A807V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.856); catalogued as COSV55332299; called by muse, mutect2, varscan2
- CLCC1 | c.1027G>T p.A343S (on ENST00000356970 / NM_001377464.1; = p.A293S on NM_015127.5) | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100206188; called by muse, mutect2
- CLCN1 | c.1498G>T p.E500* | Nonsense Mutation (SNP) | VAF 34/214 reads (16%) | catalogued as CM110546, COSV58369685, COSV58369998; called by muse, mutect2, varscan2
- CLCN3 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 67/236 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.125); catalogued as COSV100641567; called by muse, mutect2, varscan2
- CLDN7 | c.439G>T p.D147Y | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100598030; called by muse, mutect2, varscan2
- CLDND2 | c.424C>A p.L142I | Missense Mutation (SNP) | VAF 85/187 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as COSV99389786; called by muse, mutect2, varscan2
- CLEC10A | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99644518; called by muse, mutect2, varscan2
- CLEC1A | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs779048525, COSV100191095; called by muse, mutect2, varscan2
- CLEC4E | c.279C>A p.F93L | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV55225062; called by muse, mutect2, varscan2
- CLEC7A | c.634A>G p.T212A (on ENST00000304084 / NM_197947.3; = p.T166A on NM_022570.5) | Missense Mutation (SNP) | VAF 108/334 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV100045554; called by muse, varscan2
- CLIC6 | c.1489C>A p.L497I (on ENST00000360731 / NM_001317009.2; = p.L479I on NM_053277.3) | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100659105, COSV62449329; called by muse, varscan2
- CLIP1 | c.3750G>T p.E1250D (on ENST00000620786 / NM_001247997.1; = p.E1239D on NM_002956.2) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV100211126; called by muse, mutect2, varscan2
- CLIP4 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 80/208 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV100191387; called by muse, mutect2, varscan2
- CLIP4 | c.1353G>T p.K451N | Missense Mutation (SNP) | VAF 247/632 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV100191392; called by muse, mutect2, varscan2
- CLK1 | c.848A>C p.K283T | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100362106; called by muse, mutect2, varscan2
- CLK4 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 27/270 reads (10%) | catalogued as COSV100309095; called by muse, mutect2
- CLNK | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV57023865; called by muse, varscan2
- CLNS1A | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.086); catalogued as rs373008022; called by muse, mutect2, varscan2
- CLOCK | c.2355T>G p.F785L | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100011544, COSV59403818; called by muse, mutect2, varscan2
- CLOCK | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 65/239 reads (27%) | catalogued as COSV59400616; called by muse, mutect2, varscan2
- CLSTN1 | c.1540G>T p.D514Y (on ENST00000377298 / NM_001009566.3; = p.D504Y on NM_014944.4) | Missense Mutation (SNP) | VAF 86/247 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100790445; called by muse, mutect2, varscan2
- CLTC | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 7/74 reads (9%) | catalogued as COSV99291998; called by muse, mutect2, varscan2
- CLTC | c.4487C>A p.A1496D | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52248274; called by muse, mutect2, varscan2
- CLTCL1 | c.4453G>A p.D1485N | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as rs553137718, COSV54224919; called by muse, mutect2, varscan2
- CLTCL1 | c.2833C>T p.R945C | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs781816059, COSV99594469, COSV99595985; called by muse, mutect2, varscan2
- CLUAP1 | c.664T>G p.L222V | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.068); catalogued as COSV100489459; called by muse, mutect2, varscan2
- CMYA5 | c.11210C>A p.S3737* | Nonsense Mutation (SNP) | VAF 95/216 reads (44%) | catalogued as COSV71409401, COSV71410368; called by muse, mutect2, varscan2
- CNGA3 | c.1558T>C p.Y520H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99735970; called by muse, mutect2, varscan2
- CNGB1 | c.492G>T p.Q164H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV51903682; called by muse, mutect2, varscan2
- CNGB3 | c.1455T>G p.Y485* | Nonsense Mutation (SNP) | VAF 57/141 reads (40%) | catalogued as COSV100181099; called by muse, mutect2, varscan2
- CNN1 | c.16T>G p.F6V | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV52957206; called by muse, mutect2, varscan2
- CNOT1 | c.6035A>C p.N2012T | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV99799173; called by muse, mutect2, varscan2
- CNOT1 | c.1251G>T p.E417D | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57782419; called by muse, mutect2, varscan2
- CNOT1 | c.66G>T p.K22N | Missense Mutation (SNP) | VAF 60/262 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV57773806, COSV57782446; called by muse, mutect2, varscan2
- CNTLN | c.609C>A p.F203L | Missense Mutation (SNP) | VAF 122/188 reads (65%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV52101364; called by muse, varscan2
- CNTLN | c.644T>G p.F215C | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV52101372; called by muse, varscan2
- CNTN3 | c.1332G>T p.K444N | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.889); catalogued as rs1411446522, COSV99723116; called by muse, mutect2, varscan2
- CNTN3 | c.1066G>T p.A356S | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99723119; called by muse, mutect2, varscan2
- CNTN4 | c.501T>G p.D167E | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100638774; called by muse, mutect2, varscan2
- CNTN5 | c.2673G>T p.E891D | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV99672377, COSV99674766; called by muse, mutect2, varscan2
- CNTN6 | c.1771G>A p.D591N | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.772); catalogued as rs1312559913, COSV63163495; called by muse, mutect2
- CNTNAP4 | c.2651A>G p.N884S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as rs1169212925, COSV56705150; called by muse, varscan2
- CNTNAP5 | c.977T>A p.F326Y | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101442992; called by muse, varscan2
- CNTNAP5 | c.2431T>G p.F811V | Missense Mutation (SNP) | VAF 83/272 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV101442993; called by muse, mutect2, varscan2
- COBLL1 | c.2786T>G p.F929C (on ENST00000392717; = p.F891C on NM_014900.5) | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.439); catalogued as rs1209198625, COSV99527272; called by muse, varscan2
- COG3 | c.625-1G>T p.X209_splice | Splice Site (SNP) | VAF 14/67 reads (21%) | catalogued as COSV63071148; called by muse, mutect2, varscan2
- COL11A1 | c.5053G>T p.D1685Y | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62173972; called by muse, mutect2, varscan2
- COL11A1 | c.3226C>T p.R1076C | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM1411317, COSV62185763; called by muse, mutect2
- COL11A1 | c.1416C>T p.G472= | Splice Region (SNP) | VAF 69/264 reads (26%) | catalogued as rs1237983504; called by muse, mutect2, varscan2
- COL11A1 | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 79/237 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV100618280, COSV62201699; called by muse, mutect2, varscan2
- COL12A1 | c.6493G>T p.E2165* | Nonsense Mutation (SNP) | VAF 135/426 reads (32%) | catalogued as COSV100485303; called by muse, mutect2, varscan2
- COL12A1 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs563331592, COSV59401281; called by muse, mutect2, varscan2
- COL13A1 | c.386G>T p.R129I | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as COSV100637238; called by mutect2, varscan2
- COL14A1 | c.2828G>A p.R943H | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs201867541, COSV52850957; called by muse, varscan2
- COL14A1 | c.4892A>G p.H1631R | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs780491267, COSV99917821; called by muse, mutect2, varscan2
- COL16A1 | c.3150C>T p.I1050= | Splice Region (SNP) | VAF 22/81 reads (27%) | catalogued as rs368007133, COSV54705941; called by muse, mutect2, varscan2
- COL1A2 | c.3013C>T p.R1005C | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745988180, COSV99798421; called by muse, mutect2, varscan2
- COL21A1 | c.2380C>T p.R794* | Nonsense Mutation (SNP) | VAF 27/128 reads (21%) | catalogued as rs377112827, COSV55159886; called by muse, mutect2, varscan2
- COL22A1 | c.4723G>T p.D1575Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100276078, COSV57360260; called by muse, mutect2, varscan2
- COL24A1 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 94/392 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs200728036, COSV65307350; called by muse, mutect2, varscan2
- COL4A1 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV65431936; called by muse, mutect2, varscan2
- COL4A3 | c.1580T>C p.F527S | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.999); catalogued as COSV101169851; called by muse, mutect2
- COL4A3 | c.4660C>T p.P1554S | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as COSV101169853; called by muse, mutect2, varscan2
- COL4A5 | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 131/188 reads (70%) | catalogued as COSV100086348; called by muse, varscan2
- COL5A2 | c.2604G>T p.Q868H | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV100879973; called by muse, mutect2, varscan2
- COL5A2 | c.142T>C p.Y48H | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs750126490, COSV100879975; called by muse, mutect2, varscan2
- COL6A3 | c.8374G>A p.D2792N | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs746208987, COSV55084775; called by muse, mutect2, varscan2
- COL6A3 | c.3331G>A p.A1111T | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs151021451; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs767499336, COSV99796082; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A5 | c.6459C>A p.F2153L (on ENST00000312481; = p.F2149L on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/232 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55194757; called by muse, mutect2, varscan2
- COL6A6 | c.5356G>A p.D1786N | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100649734; called by muse, mutect2, varscan2
- COL9A1 | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100293943; called by muse, mutect2, varscan2
- COL9A1 | c.981A>C p.L327F | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as COSV100293948; called by muse, mutect2
- COLEC12 | c.1143T>G p.D381E | Missense Mutation (SNP) | VAF 121/621 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV101231938; called by muse, mutect2, varscan2
- COP1 | c.1988C>A p.S663Y | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV58173771, COSV58173963; called by muse, mutect2
- COPB1 | c.1540T>G p.L514V | Missense Mutation (SNP) | VAF 78/348 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.088); catalogued as COSV99999231; called by muse, mutect2, varscan2
- COPB2 | c.17A>G p.D6G | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs1560022040, COSV100300435, COSV60811728; called by muse, mutect2, varscan2
- COPRS | c.335T>A p.F112Y | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.544); catalogued as COSV100188326; called by muse, mutect2, varscan2
- COPS6 | c.472A>C p.T158P | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100384554; called by muse, mutect2
- COQ10B | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 109/287 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as rs776608625, COSV55836205; called by muse, mutect2, varscan2
- COX6C | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV99881838; called by muse, mutect2, varscan2
- CP | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 70/292 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99223665; called by muse, mutect2, varscan2
- CPEB1 | c.1135C>T p.P379S (on ENST00000617958; = p.P319S on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99917371; called by muse, mutect2, varscan2
- CPS1 | c.2667G>T p.K889N | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99241953; called by muse, mutect2
- CPXM1 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 76/202 reads (38%) | catalogued as rs201037077, COSV101013668; called by muse, mutect2, varscan2
- CR1 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV65461593; called by muse, mutect2, varscan2
- CR2 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 139/369 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100889515; called by muse, mutect2, varscan2
- CR2 | c.1187A>G p.Q396R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.881); catalogued as COSV100889517; called by muse, mutect2, varscan2
- CRB1 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 104/372 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.36); catalogued as COSV100958295; called by muse, varscan2
- CRB1 | c.296C>A p.P99H | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100958296, COSV66344110; called by muse, mutect2, varscan2
- CRB1 | c.3076T>G p.L1026V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100957639; called by muse, mutect2, varscan2
- CRBN | c.707A>C p.N236T | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.042); catalogued as COSV99214025; called by muse, mutect2
- CRHR2 | c.645G>T p.M215I | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV59263932; called by muse, mutect2, varscan2
- CRX | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs370592248; called by mutect2, varscan2
- CSF1R | c.2300C>T p.A767V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV99640724; called by muse, mutect2, varscan2
- CSMD1 | c.8487G>T p.K2829N (on ENST00000520002; = p.K2828N on NM_033225.6) | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.994); catalogued as COSV100142976, COSV100152045; called by muse, mutect2, varscan2
- CSMD1 | c.6401G>T p.R2134I (on ENST00000520002; = p.R2133I on NM_033225.6) | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100142978; called by muse, mutect2, varscan2
- CSMD1 | c.4727G>T p.R1576I (on ENST00000520002; = p.R1575I on NM_033225.6) | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs761063399, COSV100142993; called by muse, varscan2
- CSMD1 | c.2345C>A p.S782Y (on ENST00000520002; = p.S781Y on NM_033225.6) | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs766601526, COSV59294145; called by muse, mutect2, varscan2
- CSMD1 | c.992G>A p.S331N | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV101212960; called by muse, mutect2, varscan2
- CSMD2 | c.5660A>G p.Y1887C | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV99585428; called by muse, mutect2, varscan2
- CSMD3 | c.2047C>T p.R683C (on ENST00000297405 / NM_001363185.1; = p.R579C on NM_052900.3) | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1266203286, COSV52185681; called by muse, mutect2, varscan2
- CSNK1A1L | c.309C>A p.F103L | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.03); catalogued as COSV65789520; called by muse, mutect2, varscan2
- CSPP1 | c.2320G>T p.E774* (on ENST00000676605; = p.E733* on NM_024790.6) | Nonsense Mutation (SNP) | VAF 21/81 reads (26%) | catalogued as COSV99137981; called by muse, mutect2, varscan2
- CSRNP1 | c.1368G>T p.E456D | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.569); catalogued as COSV99826673; called by muse, mutect2, varscan2
- CSRNP3 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); catalogued as rs774567924, COSV100086475, COSV58787933; called by muse, mutect2, varscan2
- CTAGE1 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV66945339; called by muse, mutect2, varscan2
- CTCFL | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 164/440 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as rs765675257, COSV54773669; called by muse, varscan2
- CTHRC1 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 93/257 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767759004, COSV100372900; called by muse, mutect2, varscan2
- CTNNA2 | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | catalogued as COSV100559375, COSV58144333; called by muse, varscan2
- CTNNA2 | c.2234C>T p.A745V | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV58136714, COSV58173769; called by muse, mutect2, varscan2
- CTNNA3 | c.1766C>G p.A589G | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101045581; called by muse, mutect2, varscan2
- CTNND2 | c.2800A>G p.M934V | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.448); catalogued as COSV100471218; called by muse, mutect2, varscan2
- CUBN | c.1291G>T p.E431* | Nonsense Mutation (SNP) | VAF 69/156 reads (44%) | catalogued as COSV100912010, COSV100913379; called by muse, mutect2, varscan2
- CUL4B | c.2488G>T p.E830* | Nonsense Mutation (SNP) | VAF 22/29 reads (76%) | catalogued as COSV100340091; called by muse, mutect2, varscan2
- CUL4B | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as COSV60685068; called by muse, mutect2, varscan2
- CUL9 | c.3041C>A p.S1014Y | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV99334669; called by muse, mutect2, varscan2
- CWC15 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 156/667 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs1555095301, COSV99688423; called by muse, varscan2
- CWC22 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99843910; called by muse, mutect2, varscan2
- CWF19L2 | c.1230G>T p.K410N | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV56510118; called by muse, mutect2, varscan2
- CXorf58 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 77/112 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101002921; called by muse, mutect2, varscan2
- CYLC1 | c.781T>G p.F261V | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV61415630; called by muse, mutect2
- CYLC1 | c.1571T>G p.F524C | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV61414395; called by muse, mutect2
- CYLC2 | c.14G>T p.R5I | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs956648077, COSV66336380; called by muse, mutect2, varscan2
- CYLC2 | c.617C>A p.S206Y | Missense Mutation (SNP) | VAF 223/667 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1450937114; called by muse, mutect2, varscan2
- CYLC2 | c.959A>C p.K320T | Missense Mutation (SNP) | VAF 179/565 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV100872347; called by muse, mutect2, varscan2
- CYP11A1 | c.846G>T p.Q282H | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV99165881; called by muse, mutect2, varscan2
- CYP11B2 | c.1508A>C p.N503T | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs146765393; called by muse, mutect2, varscan2
- CYP26A1 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56416825; called by muse, mutect2, varscan2
- CYP27A1 | c.1238T>G p.V413G | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs587778783, CM121352, COSV99298313; called by muse, mutect2, varscan2
- CYP2C19 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs138112316, COSV64907487; called by muse, mutect2, varscan2
- CYP3A4 | c.383G>T p.R128I | Missense Mutation (SNP) | VAF 21/238 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV60504759; called by muse, mutect2
- CYP3A5 | c.742T>G p.F248V | Missense Mutation (SNP) | VAF 119/278 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99769452; called by muse, mutect2, varscan2
- CYP3A7 | c.932G>T p.S311I | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100312530; called by muse, mutect2, varscan2
- CYP4B1 | c.1299G>T p.E433D | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as COSV54722940, COSV99596745; called by muse, mutect2, varscan2
- CYP51A1 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 123/316 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs776540678, COSV50151372; called by muse, mutect2, varscan2
- CYP51A1 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 48/174 reads (28%) | catalogued as COSV99133562; called by muse, mutect2, varscan2
- CYRIA | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 44/164 reads (27%) | catalogued as rs776202730, COSV62866091; called by muse, varscan2
- CYRIA | c.307C>A p.L103I | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.291); catalogued as COSV62867145; called by muse, varscan2
- CYTIP | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.88); PolyPhen benign (0.018); catalogued as rs1168235702, COSV99938616; called by muse, mutect2, varscan2
- DAAM1 | c.1949C>T p.S650F | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100658095; called by muse, mutect2, varscan2
- DAB2 | c.1589G>T p.G530V | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); catalogued as COSV100297757, COSV57913556; called by muse, mutect2, varscan2
- DACH2 | c.1566G>T p.E522D | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV100912428; called by muse, mutect2, varscan2
- DAPK1 | c.461A>C p.K154T | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.089); catalogued as rs758563684, COSV100800878; called by muse, mutect2, varscan2
- DCAF12L2 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63583212, COSV63584206; called by muse, varscan2
- DCAF13 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 92/232 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs761547809, COSV52571384; called by muse, mutect2, varscan2
- DCAF4L2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV60481465, COSV60482929, COSV99081978; called by muse, mutect2, varscan2
- DCAF6 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 95/328 reads (29%) | catalogued as COSV100393820, COSV56576961; called by muse, varscan2
- DCAF8 | c.1389G>T p.E463D | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100470101; called by muse, mutect2, varscan2
- DCAF8 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100470105; called by muse, mutect2, varscan2
- DCBLD1 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.23); catalogued as rs1345084436, COSV99757006; called by muse, mutect2, varscan2
- DCDC1 | c.4711T>G p.L1571V (on ENST00000597505 / NM_001367979.1; = p.L678V on NM_020869.3) | Missense Mutation (SNP) | VAF 27/462 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58004321; called by muse, mutect2
- DCDC2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 53/82 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99219658; called by muse, mutect2, varscan2
- DCLRE1A | c.3091T>G p.F1031V | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV100800190; called by muse, mutect2, varscan2
3,909 further variants in this file (2,950 protein-altering or splice-affecting, 862 silent, 97 other) are not listed here.
